Surgical pathology report (de-identified scan), TCGA case TCGA-73-7499, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-73-7499-01A (Primary Tumor).

[page 1 of 3]
TSS: [REDACTED]

SPECIMENS:

- A. 4R LYMPH NODE
- B. 2ND 4R LYMPH NODE
- C. 4L SUPERIOR LYMPH NODE
- D. 4L INFERIOR LYMPH NODE
- E. LEVEL 7 LYMPH NODE
- F. 2R LYMPH NODE
- G. 2L LYMPH NODE
- H. RIGHT UPPER LOBE
- I. LEVEL 4R LYMPH NODES
- J. LEVEL 7 LYMPH NODES

SPECIMEN(S):

- A. 4R LYMPH NODE
- B. 2ND 4R LYMPH NODE
- C. 4L SUPERIOR LYMPH NODE
- D. 4L INFERIOR LYMPH NODE
- E. LEVEL 7 LYMPH NODE
- F. 2R LYMPH NODE
- G. 2L LYMPH NODE
- H. RIGHT UPPER LOBE
- I. LEVEL 4R LYMPH NODES
- J. LEVEL 7 LYMPH NODES

DIAGNOSIS:

- A. LYMPH NODE, 4R, BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- B. LYMPH NODE, ADDITIONAL 4R, BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- C. LYMPH NODE, 4L SUPERIOR, BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- D. LYMPH NODE, 4L INFERIOR, BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- E. LYMPH NODE, LEVEL 7, BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- F. LYMPH NODE, 2R, BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- G. LYMPH NODE, 2L, BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- H. LUNG, RIGHT UPPER LOBE, LOBECTOMY:
- INFILTRATIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA (3CM).
- BRONCHIAL MARGIN IS NOT INVOLVED.
- ONE BENIGN PERIBRONCHIAL LYMPH NODE (0/1).
- I. LYMPH NODE, 4R, DISSECTION:
- FIVE BENIGN LYMPH NODE (0/5).
- J. LYMPH NODE, LEVEL7, DISSECTION:
- NINE BENIGN LYMPH NODE (0/9).

SYNOPTIC REPORT - LUNG

Specimens Involved

Specimens: H: RIGHT UPPER LOBE

[page 2 of 3]
TSS: [REDACTED]

Surgical Procedure: Lobectomy
Laterality: Right
Tumor Site: Upper lobe
Tumor Location: Peripheral
Tumor Size: Greatest diameter: 3cm
Additional dimensions: 2.5cm x 2cm
WHO CLASSIFICATION
Adenocarcinoma
Mixed subtypes 8255/3
Dominant Histologic Subtype: Acinar
Proportion of Subtype: Lepidic 40% Acinar 50% Solid 10%
Histologic Grade: G2: Moderately differentiated
Angiolymphatic Invasion: Absent
Bronchial Margins: Bronchial margins uninvolved
Tumor Distance from margin: 2cm
Visceral Pleural Involvement: Absent
Satellite Tumor(s): Absent
Lymph Node Involvement: N1: Ipsilateral Hilar and/or Peribronchial (levels 10-14)
Negative 0 / 1
N2: Ipsilateral Mediastinal and/or Subcarinal (Levels 1-9)
Negative 0 / 18
N3: Contralateral Mediastinal/Hilar, Scalene or Supraclavicular
Negative 0 / 2
Non-Neoplastic Lung: Emphysematous changes
Atelectasis
Additional Pathologic Findings: None identified
Pathological Staging (pTNM): pT 2a N 0 M x
Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

GROSS DESCRIPTION:

A. 4R LYMPH NODE

Received fresh for frozen section labeled with the patient's identification and '4R lymph node' are multiple tan red soft tissue fragments aggregating to 1.1 x 0.9 x 0.3cm. Toto FSA.

B. 2ND 4R LYMPH NODE

Received fresh for frozen section labeled with the patient's identification and '2nd 4R lymph node' are multiple tan red soft tissue fragments aggregating to 1.2 x 0.9 x 0.3cm. Toto FSB.

C. 4L SUPERIOR LYMPH NODE

Received fresh for frozen section labeled with the patient's identification and '4L superior lymph node' are multiple tan red soft tissue fragments aggregating to 0.8 x 0.8 x 0.2cm. Toto FSC.

D. 4L INFERIOR LYMPH NODE

Received fresh for frozen section labeled with the patient's identification and '4L inferior lymph node' are multiple tan red soft tissue fragments aggregating to 0.8 x 0.4 x 0.4cm. Toto FSD.

E. LEVEL 7 LYMPH NODE

Received fresh for frozen section labeled with the patient's identification and 'Level 7 lymph node' are multiple tan red soft tissue fragments aggregating to 0.8 x 0.8 x 0.3cm. Toto FSE.

F. 2R LYMPH NODE

Received fresh for frozen section labeled with the patient's identification and '4R lymph node' are two tan red soft tissue fragments aggregating to 0.8 x 0.4 x 0.2cm. Toto FSF.

G. 2L LYMPH NODE

Received fresh for frozen section labeled with the patient's identification and '4L lymph node' are multiple tan red soft tissue fragments aggregating to 0.6 x 0.3 x 0.3cm. Toto FSG.

[REDACTED] UPPER LOBE LUNG

Received fresh labeled with the patient's identification and designated "right upper lobe" is a right upper lung lobectomy specimen, weighing 198 grams and measuring 16 x 8 x 3.2 cm. The pleural surface demonstrates an area of puckering, 2.1 x 1.3 cm, inked black. Sectioning shows a gray-tan mass measuring 3 x 2.5 x 2.0 cm, located approximately 2 cm from bronchial margin and 1.3 cm from pleural surface. The remainder of the specimen shows pink red congested lung parenchyma. A portion of the specimen is submitted for tissue procurement. Representative sections submitted:

H1: Bronchial margin from the frozen section

H2: Tumor section, from the frozen section

H3-4: Tumor with pleura

[page 3 of 3]
TSS: [REDACTED]

H5: Tumor with closest bronchial branch

H6-7: Section from puckering area

H8: Uninvolved lung parenchyma

H9: Hilar lymph nodes

I. LEVEL 4R LYMPH NODES

Received in formalin labeled with the patient's identification and "level 4R lymph nodes" are pieces of yellow-tan soft tissue admixed with black-tan lymph nodes in aggregate measuring 3.1 x 2.4 x 0.6 cm; submitted entirely in cassettes I1-I2.

J. LEVEL 7 LYMPH NODE

Received in formalin labeled with the patient's identification and "level 7 lymph node" is an aggregate of black-tan lymphoid tissue pieces, 3 x 2 x 0.7 cm; submitted entirely in cassettes J1-J2.

CLINICAL HISTORY:

None provided.

PRE-OPERATIVE DIAGNOSIS:

Right upper lobe mass.

INTRA-OPERATIVE DIAGNOSIS:

FSA-FSB-FSC: 4R LN- 2nd 4R LN- 4L superior LN: Negative for carcinoma. Diagnosis called to [REDACTED]

FSD-FSE-FSF-FSG: 4L inferior LN-Level 7 LN-2R LN- 2L LN: Negative for carcinoma. Diagnosis called to [REDACTED]

FS H1, Bronchial margin: Negative for malignancy, one peribronchial lymph node negative for malignancy.

FSH2, Tumor section: Non-small cell carcinoma, favor adenocarcinoma.

Report called to [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 59315744-9181-4861-a850-2d3bb3b78a0e (TCGA-73-7499.8D4F6D68-7F74-4DEF-A235-A36A70F83EBE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).